Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A7BT, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A7BT-01A (Primary Tumor).

[page 1 of 3]
DOB:
Male

Specimen No.

Collected:

Received:

HISTOPATHOLOGY

Lab No:

CLINICAL NOTES:

Subtotal gastrectomy and extended right hemicolectomy for adenocarcinoma of distal gastric region. ?spread to transverse colon. Peritoneal nodule.

MACROSCOPIC DESCRIPTION:

1. A stomach and extended right hemicolectomy connected by attached gastrocolic omentum. The proximal gastric margin measures 60mm in diameter and the distal margin measures 35mm in diameter. The lesser curvature measures 120mm and the greater curvature measures 165mm. The lesser omentum measures 35mm in width. The greater omentum measures 170mm in width.

The right hemicolectomy specimen consists of terminal ileum, 100mm in length x 25mm in diameter, appendix 80x5mm and right colon 550mm in length x 25mm in diameter.

There is a fungating ulcerated tumour plaque in the lesser curve of the stomach. 75x82mm, approximately 20mm from the proximal resection margin and 40mm from the distal resection margin. Tumour is up to 18mm thick and has penetrated the full thickness of the stomach wall to infiltrate up to approximately 10mm into lesser omentum. There is no macroscopic direct extension of tumour into the greater/gastrocolic omentum, however, numerous nodules suspicious of tumour metastases are evident within both greater and lesser omenta in the vicinity of the stomach.

The right hemicolectomy specimen is macroscopically unremarkable.

A sample of fresh gastric tumour was given to for research purposes.

- Block 1A-1C - Proximal margin (posterior surface).
1D - Anterior surface distal margin.
1E - Tumour and lesser omentum.
1F-1H - Tumour and posterior surface of stomach.
1I - Tumour and anterior surface of stomach.
1J-1M - Lesser omental nodes.
1N - Nodular surface posterior stomach.
1O - Nodes greater curvature.
1P - Nodes greater curvature.
1Q-1R - Nodules gastrocolic mesentery.
1S - Greater omentum.
1T - Gastrocolic nodules.

ICD O-3

Adenocarcinoma, intestinal type
C68.0 8/4/13

Site Fundus & stomach
pylorus
9/28/13
C68.1
C68.4

Please contact the authorising Pathologist if you wish to discuss this case.

For enquiries on this test report please contact
AUTHORISED BY

FINAL - File Permanently

This is a COPY

Printed:
Page 1 of 3

HISTOLOGY

[page 2 of 3]
DOB:
Male

Specimen No.

Collected:

Received:

- 1U - Margins of bowel.
- 1V - Appendix.
- 1W - Large bowel apical nodes. P23.

2. "Peritoneal". A peritoneum 40x30mm. The central portion is thickened. There is an area of skeletal muscle. P1.

MICROSCOPIC DESCRIPTION:

1. Sections show a large poorly differentiated gastric adenocarcinoma of intestinal type which extends with an infiltrating margin through the full thickness of stomach wall into subserosal tissues and omenta. Although tumour lies immediately beneath the peritoneal surface, no actual breach of the peritoneum by tumour is identified in the sections examined.

Tumour consists of solid cohesive masses of cells, focally punctuated by infrequent small granular lumina. Small quantities of desmoplastic stroma are focally associated with tumour, however, in many areas, there is no appreciable stromal response.

Individual tumour cells are large round to polygonal cells with moderate quantities of amphophilic cytoplasm, large moderately pleomorphic rounded nuclei, granular to irregularly clumped chromatin and conspicuous large amphophilic nucleoli. Mitoses are abundant.

There is extensive tumour invasion of lymphatic vessels, both within the gastric wall and within omenta. There is, additionally, apparent focal invasion of ectatic veins within omenta. There are numerous deposits of metastatic tumour within omenta, both within lymph nodes and as separate nodules growing directly out of lymphatic vessels. Exact counting of these is very difficult, however, at least 55 apparently distinct metastases are present amongst 56 lymph nodes and omental tumour nodules (present in both lesser and greater omenta).

Tumour within mural lymphatic vessels appears to have approached to within 1.5mm of the proximal longitudinal resection margin of the stomach, but is nevertheless completely excised in the planes of section. Tumour appears to be well clear of the distal resection margin.

No tumour is identified within the right hemicolectomy specimen, including 5 ileocolic lymph nodes.

2. Sections show skeletal muscle and peritoneum. No tumour is identified in this specimen.

DIAGNOSIS:

Please contact the authorising Pathologist if you wish to discuss this case.

For enquiries on this test report please contact
AUTHORISED BY

FINAL - File Permanently

This is a COPY

Printed:
Page 2 of 3

HISTOLOGY

[page 3 of 3]
DOB:
Male

Specimen No.

Collected:

Received:

1. DISTAL SUBTOTAL GASTRECTOMY AND EXTENDED RIGHT HEMICOLECTOMY:
POORLY DIFFERENTIATED GASTRIC ADENOCARCINOMA, INFILTRATING SUBSEROSA,
WITH EXTENSIVE LYMPHOVASCULAR INVASION, NARROWLY EXCISED (1.5MM) AT THE
PROXIMAL LONGITUDINAL RESECTION MARGIN; TUMOUR METASTASES TO AT LEAST
55 OF 56 REGIONAL LYMPH NODES; RIGHT HEMICOLECTOMY WITHIN NORMAL
LIMITS.

2. PERITONEAL BIOPSY:
NO TUMOUR IDENTIFIED.

AJCC STAGE IV (T2,N3,MX).

Pathologist:

HI/PA Discrepancy		

Please contact the authorising Pathologist if you wish to discuss this case.

For enquiries on this test report please contact
AUTHORISED BY

FINAL - File Permanently

This is a COPY

Printed:
Page 3 of 3

HISTOLOGY

Source: NCI Genomic Data Commons file a741e196-b284-43ee-85a9-552d1b4b53a5 (TCGA-RD-A7BT.231D1C1E-6804-4935-8802-AAA92EFD9F78.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).